Gene-level copy-number profile of specimen HCM-BROD-0482-C34-85M from HCMI case HCM-BROD-0482-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 54.5 years (19,904 days).
Specimen HCM-BROD-0482-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 604f46d3-221c-414c-8001-08a0ff029de7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0482-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,254 have no estimate.
https://portal.gdc.cancer.gov/files/ab0cd226-82f4-4b89-8a84-be92dcd03f8c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 939; copy number 2: 6,743; copy number 3: 18,499; copy number 4: 14,988; copy number 5: 12,504; copy number 6: 3,043; copy number 7: 208; copy number 8: 1,089; copy number 9: 102; copy number 10: 16; copy number 11: 41; copy number 12: 38; copy number 13: 96; copy number 15: 3; copy number 180: 1; copy number 267: 2; copy number 271: 2; copy number 288: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr15:21,080,812–21,081,447, 1 gene: BCAR1P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,536 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes, copy number 8: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:58,198–1,445,440, 52 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3.
- chr7:1,152,071–2,775,500, 39 genes, copy number 9 (within-gene range 5–9): ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655, MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1.
- chr9:12,134–33,039,907, 413 genes, copy number 8–12 (within-gene range 8–13) (broad region; genes not listed).
- chr9:33,247,820–36,677,683, 161 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr13:61,805,150–62,029,572, 3 genes, copy number 8: RAC1P8, AL353765.1, LINC00358.
- chr13:63,851,197–64,076,044, 1 gene, copy number 8 (within-gene range 2–8): LINC00355.
- chr13:64,958,097–65,310,953, 2 genes, copy number 7: LGMNP1, STARP1.
- chr13:71,296,210–71,297,235, 1 gene, copy number 7: RABEPKP1.
- chr13:74,231,457–74,259,976, 1 gene, copy number 7: LINC00402.
- chr13:74,552,503–74,565,445, 1 gene, copy number 7 (within-gene range 6–7): LINC00347.
- chr13:77,895,481–78,617,328, 3 genes, copy number 7 (within-gene range 6–7): EDNRB, OBI1-AS1, AL139002.1.
- chr13:77,979,817–78,488,513, 7 genes, copy number 7 (within-gene range 6–7): LINC01069, LINC00446, AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23.
- chr13:78,761,175–78,840,051, 2 genes, copy number 7: RPL21P111, LINC00331.
- chr13:78,908,919–79,094,119, 2 genes, copy number 7: CCT5P2, NIPA2P5.
- chr13:79,311,824–79,406,477, 1 gene, copy number 7 (within-gene range 6–7): RBM26.
- chr13:79,872,586–79,918,042, 1 gene, copy number 7: LINC00382.
- chr13:94,436,811–94,479,682, 1 gene, copy number 7: DCT.
- chr13:94,960,041–95,007,420, 2 genes, copy number 7: LINC00557, AL139381.1.
- chr13:97,675,011–97,677,963, 1 gene, copy number 7: AL359502.1.
- chr13:98,629,686–99,086,625, 7 genes, copy number 7 (within-gene range 6–7): CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1.
- chr13:99,025,234–99,025,345, 1 gene, copy number 7: RNU6-83P.
- chr13:99,446,311–99,583,180, 6 genes, copy number 7: TM9SF2, LINC01232, AL139035.1, LINC00449, LINC01039, CFL1P8.
- chr13:103,420,825–103,444,968, 2 genes, copy number 9: LINC01309, ATP6V1G1P7.
- chr13:105,459,055–105,505,681, 4 genes, copy number 7: DAOA-AS1, AL359751.2, AL359751.1, DAOA.
- chr13:106,155,372–106,155,490, 1 gene, copy number 7: RNA5SP38.
- chr13:106,863,816–106,942,561, 3 genes, copy number 7: PPIAP24, AL162574.1, AL162574.3.
- chr13:112,106,095–113,554,590, 39 genes, copy number 7–12: LINC00404, LINC01070, LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1.
- chr14:41,607,570–42,808,112, 8 genes, copy number 7: LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1.
- chr15:20,759,311–20,775,998, 3 genes, copy number 15: AC012414.2, AC012414.3, LONRF2P3.
- chr20:56,267,872–56,269,231, 1 gene, copy number 7: AL139824.2.
- chr20:58,309,715–64,327,972, 193 genes, copy number 7–13 (broad region; genes not listed).
- chr21:19,739,709–44,262,216, 488 genes, copy number 8 (broad region; genes not listed).
- chr21:44,450,986–46,057,567, 76 genes, copy number 7 (broad region; genes not listed).
- chr21:46,458,891–46,605,208, 4 genes, copy number 7: DIP2A, DIP2A-IT1, RNU6-396P, S100B.

Autosomal genes at a single copy (total copy number 1): 259. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
